FM case AD4797 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/9e335695-2e6e-4486-9383-9e8cbddeca29

Male, 71.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the peritoneum; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
